Gene-level copy-number profile of tumor specimen C3N-04124-01 (profiled together with C3N-04124-02) from CPTAC case C3N-04124, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 62.7 years (22,895 days).
Specimen C3N-04124-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 31dd4877-d3ad-4fdd-99e4-8315c889e31e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-04124-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/7ccf3af1-cb32-4eaf-a915-65db8b52411a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 398; copy number 1: 6,471; copy number 2: 45,945; copy number 3: 3,933; copy number 4: 965; copy number 5: 387; copy number 6: 77; copy number 7: 35; copy number 8: 16; copy number 9: 63; copy number 10: 367; copy number 11: 79; copy number 12: 21; copy number 13: 41; copy number 15: 56; copy number 19: 43; copy number 40: 7.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:86,481,943–90,261,708, 34 genes: LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr4:4,126,659–4,150,421, 2 genes: OR7E103P, UNC93B4.
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr9:61,615,835–61,627,683, 1 gene: FAM242D.
- chr9:138,199,933–138,253,217, 2 genes: AL954642.1, FAM157B.
- chr14:97,749,264–97,763,989, 1 gene: LINC02312.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,192 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,548,562–150,629,612, 10 genes, copy number 8: ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4.
- chr1:160,537,073–161,238,244, 43 genes, copy number 5: AL138930.1, CD84, SLAMF1, SETP9, AL121985.1, CD48, SLAMF7, AL121985.3, AL121985.2, LY9, CD244, PPIAP37, ITLN1, AL354714.2, AL354714.3, AL354714.1, AL354714.4, ITLN2, F11R, AL591806.2, GLRX5P2, TSTD1, USF1, ARHGAP30, NECTIN4, NECTIN4-AS1, KLHDC9, PFDN2, NIT1, DEDD, AL591806.1, UFC1, AL590714.1, USP21, PPOX, B4GALT3, ADAMTS4, NDUFS2, FCER1G, APOA2, TOMM40L, MIR5187, NR1I3.
- chr3:115,802,363–117,139,389, 1 gene, copy number 5 (within-gene range 2–5): LSAMP.
- chr3:116,360,024–125,937,039, 176 genes, copy number 5 (broad region; genes not listed).
- chr3:134,055,256–134,575,017, 14 genes, copy number 6: LINC02000, RYK, HMGB3P14, LINC02004, AC010207.1, RPL39P5, AMOTL2, MIR6827, HMGN1P9, HMGB3P13, MIR4788, ANAPC13, CEP63, AC026117.1.
- chr3:137,998,735–138,033,655, 1 gene, copy number 6 (within-gene range 2–6): CLDN18.
- chr3:138,061,990–138,174,921, 5 genes, copy number 6: DZIP1L, KRT8P36, A4GNT, AC023049.1, DBR1.
- chr3:146,069,440–153,980,186, 138 genes, copy number 5–13 (within-gene range 2–13) (broad region; genes not listed).
- chr3:154,969,283–172,725,038, 255 genes, copy number 5–10 (broad region; genes not listed).
- chr3:178,960,121–182,921,629, 79 genes, copy number 10 (within-gene range 2–10) (broad region; genes not listed).
- chr3:183,015,218–183,116,075, 1 gene, copy number 5 (within-gene range 2–5): MCCC1.
- chr3:183,122,215–183,684,519, 14 genes, copy number 5–7: LAMP3, MCF2L2, B3GNT5, RNA5SP151, LINC00888, SNORA63D, AC092960.2, SNORA63E, AC092960.1, AC092960.3, KLHL6, KLHL6-AS1, AC068769.1, KLHL24.
- chr3:186,781,780–190,322,446, 55 genes, copy number 5: AC112907.3, EIF4A2, SNORD2, SNORA63B, MIR1248, SNORA81, SNORA63, SNORA4, RFC4, AC112907.1, LINC02043, AC112907.2, ADIPOQ, ADIPOQ-AS1, RPS20P14, AC007690.1, ST6GAL1, RPL39L, AC007920.1, RTP1, MASP1, AC007920.2, RTP4, AC068299.2, AC068299.1, LINC02041, SST, RTP2, AC072022.1, BCL6, AC072022.2, AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2, LPP, FLJ42393, LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1.
- chr3:194,070,103–194,689,037, 25 genes, copy number 7 (within-gene range 2–7): AC024559.2, AC080129.1, AC080129.2, HES1, RN7SL215P, LINC02036, LINC02037, LINC02048, LINC00887, AC117469.1, CPN2, LRRC15, GP5, ATP13A3, AC108676.2, LINC00884, AC108676.1, RNU6-1101P, RPL23AP93, TMEM44-AS1, TMEM44, AC046143.1, AC046143.2, LSG1, FAM43A.
- chr5:24,772,144–24,910,695, 6 genes, copy number 5–6: AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA.
- chr9:35,592,786–37,047,237, 59 genes, copy number 13–40: RPS29P17, TESK1, MIR4667, CD72, AL357874.2, AL357874.1, SIT1, RMRP, RMRP, CCDC107, ARHGEF39, RN7SL22P, CA9, TPM2, TLN1, MIR6852, CREB3, MIR6853, GBA2, RGP1, MSMP, AL133410.2, AL133410.1, NPR2, SPAG8, HINT2, AL133410.3, TMEM8B, FAM221B, OR13E1P, OR13J1, NDUFA5P4, HRCT1, SPAAR, PGAM1P2, OR2S2, OR2S1P, YBX1P10, OR13C6P, OR13C7, OR2AM1P, RECK, AL138834.1, GLIPR2, CCIN, CLTA, GNE, RNU4-53P, HMGB3P24, RNF38, MELK, AL450267.2, MIR4475, PAX5, AL450267.1, MIR4540, MIR4476, AL161781.2, AL161781.1.
- chr9:37,383,178–60,964,196, 164 genes, copy number 5–15 (broad region; genes not listed).
- chr9:61,581,813–61,582,675, 1 gene, copy number 10: AL935212.3.
- chr9:62,387,171–63,143,401, 30 genes, copy number 10: AL590399.5, AL590399.2, BX664725.1, LINC01189, FGF7P7, BX005266.2, BX005266.1, CNTNAP3P5, RBPJP7, RAB28P2, BX005266.3, ATP5F1AP7, SDR42E1P3, FKBP4P7, LINC01410, AL512625.3, RNA5SP283, AL512625.2, PTGER4P2, CDK2AP2P2, LERFS, MYO5BP2, ADGRF5P1, FGF7P8, AL512625.1, CNTNAP3P1, AL591379.2, BMS1P9, AL591379.1, AQP7P4.
- chr9:64,369,394–66,179,474, 45 genes, copy number 10–11: ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1, AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2, BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P, BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1, FOXD4L5, CBWD4P, Y_RNA, FRG1KP, CBWD5, FOXD4L4, IGKV1OR-3, BX284632.2, BX284632.1, BMS1P13, AC129778.1, AQP7P3, AL136317.2, AL136317.1, GXYLT1P4, AL136317.3, AL669942.2, AL669942.1, AL513478.4, SNX18P4, AL513478.1, ANKRD20A3P, RNU6-538P.
- chr9:68,302,867–68,330,626, 3 genes, copy number 5 (within-gene range 2–5): FOXD4L3, AL353608.3, AL353608.1.
- chr15:70,853,239–71,053,658, 1 gene, copy number 5 (within-gene range 3–5): LRRC49.
- chr15:70,881,342–73,305,205, 52 genes, copy number 5 (within-gene range 3–5): THAP10, RPL5P3, THSD4, CT62, THSD4-AS1, HMGB1P6, AC064799.2, AC064799.1, AC108861.1, NR2E3, AC104938.1, MYO9A, RNA5SP399, AC022872.1, EIF5A2P1, RNU2-65P, SENP8, AC020779.1, AC020779.2, GRAMD2A, PKM, PARP6, AC009690.3, AC009690.2, CELF6, AC009690.1, HEXA, HEXA-AS1, RPL12P35, TMEM202, TMEM202-AS1, PHBP20, AC079322.1, ARIH1, MIR630, AC100827.3, AC100827.5, AC100827.2, LINC02259, AC100827.4, AC100827.1, GOLGA6B, RN7SL853P, HIGD2B, AC009712.1, BBS4, ADPGK, ADPGK-AS1, NPM1P42, NEO1, FKBP1AP2, NPM1P43.
- chr17:33,013,087–34,174,964, 1 gene, copy number 10 (within-gene range 2–10): ASIC2.
- chr17:33,529,787–34,156,000, 10 genes, copy number 10 (within-gene range 2–10): AA06, AC011824.3, AC011824.2, AC011824.1, AC024614.1, AC024614.2, AC024614.3, AC024614.4, AC024610.2, AC004147.4.
- chr17:34,155,566–34,165,736, 1 gene, copy number 10 (within-gene range 2–10): AC004147.2.
- chr20:25,611,153–25,624,014, 2 genes, copy number 6: RNU6ATAC17P, NANP.

Autosomal genes at a single copy (total copy number 1): 4,138. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
